Surgical pathology report (de-identified scan), TCGA case TCGA-X9-A971, project TCGA-SARC (Sarcoma), tissue source site University of California, Davis, specimen TCGA-X9-A971-01A (Primary Tumor).

[page 1 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

REG DR:

AGE/SX: /F

DOB:

STATUS:

SPEC #: [REDACTED]

RECV:

STATUS:

REQ #:

ORD LOC:

SPEC:

SUBM DR:

TYPE: SURG PATH

ASSN TO:

PT AGE AT RECV:

REASON FOR VISIT: SOFT TISSUE CA NOS

ENTERED:

OTHR DR:

DEPT:

LAST RPTD:

LAST ACT:

TAT HRS:

SLIDES:

ORDERED: G&M Level 5, Desmin, S100 Neural Ant, Vimentin, CD-34, Ki-67 quant/sem,
Smooth Muscle A

DELETED: NO CHARGE -

ORD SITE:

TRANSIT SITE:

RCV SITE:

PERFORM SITE:

AT SITE:

RPT AUDIT:

ICD-O-3

Lymphoma NOS 8890/3

Site: Shoulder NOS C49.1

QD 5/19/14

STATUS HX:

ACTIVITY	DATE	TIME	TYPE	RECORD	STATUS	USER
1					SENT	
2					SENT	

Continued on next page ...

[page 2 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #: [REDACTED] PATIENT: [REDACTED] ACCT #: [REDACTED]

CODES: TY1220 - Shoulder
Edited by:

PROCEDURES: G&M Level 5
Desmin
S100 Neural Ant
Vimentin
CD-34
Ki-67 quant/sem
Smooth Muscle A

Edited by:

TISSUES:
A. Shoulder - RIGHT SHOULDER SARCOMA MASS
Edited by:

CLINICAL INFORMATION

Suspected Diagnosis: Right shoulder soft tissue mass
Clinical Information: Leiomyosarcoma
Collected by:
Other/Special Requests: Attn: [REDACTED]
Edited by:

GROSS DESCRIPTION

A. Received without fixative, designated as "right shoulder sarcoma; short - superior; long - lateral," is an oriented 241 grams, 13.7 x 9.5 x 4.4 cm segment of soft tissue which is partially covered by an 11.7 x 3.6 cm lenticular segment of wrinkled pink-tan skin. Margins are inked as follows: deep - black; superficial-superior - blue; superficial-inferior - green. The specimen is sectioned from medial to lateral revealing a 3.8 x 3.4 x 2.5 cm ill-defined, indurated, pink to white fibrous tumor (0.2 cm from deep; 1.1 cm from the skin surface; 3.3 cm from superior; 2.6 cm from inferior; 4.5 cm from medial; 3.4 cm from lateral). Tissue is collected for research. Tissue is forwarded for cytogenetic analysis.

Summary of sections:

A1-A4	tumor to deep
A5	tumor to skin
A6	superior margin
A7	inferior margin
A8	medial margin
A9	lateral margin
A10	additional tumor

Edited by:

Continued on next page ...

[page 3 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #: [REDACTED]

PATIENT: [REDACTED]

ACCT #: [REDACTED]

GROSS DESCRIPTION

(Continued)

ICD 9 DATA CAPTURE

ICD-9 171.2 Modifier

Discrepancy CODER

Entry Date

Review by

Review Date

Edited by:

MICROSCOPIC DESCRIPTION

Slides were examined microscopically and the diagnosis for each specimen incorporates the pathologist's interpretation.

Edited by:

DIAGNOSIS

A. SOFT TISSUE, RIGHT SHOULDER (EXCISION):

- LEIOMYOSARCOMA WITH PLEOMORPHIC FEATURES, HIGH GRADE, SEE SYNOPTIC REPORT.
- IMMUNOHISTOCHEMISTRY:
- ACTIN (SMA) - POSITIVE
- VIMENTIN - POSITIVE
- DESMIN - NEGATIVE
- S100 - NEGATIVE
- CD34 - NEGATIVE
- KI67 - POSITIVE, NUCLEAR STAIN ABOUT 60%

SYNOPTIC REPORT:

SOFT TISSUE: Resection

Tumor Site:

Right shoulder

Tumor Size

Greatest dimension: 3.8 cm

Macroscopic Extent of Tumor:

Subcutaneous/suprafascial

Histologic Type (World Health Organization [WHO] classification of soft tissue tumors):

Leiomyosarcoma, high grade

Mitotic Rate:

Specify: more than 5 /10 high-power fields (HPF)

Necrosis:

Present

Extent: 5%

Margins:

Margins negative for sarcoma

Continued on next page ...

[page 4 of 4]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 4

SPEC #: [REDACTED]

PATIENT: [REDACTED]

ACCT #: [REDACTED]

DIAGNOSIS

(Continued)

Pathologic Staging (pTNM):

Primary Tumor (pT)

pT1a: Tumor 5 cm or less in greatest dimension, superficial tumor

Regional Lymph Nodes (pN):

pNX: Regional lymph nodes cannot be assessed

No nodes submitted or found

Distant Metastasis (pM):

Not applicable

Edited by:

RESIDENT ASSIGNED

NONE

Edited by:

Final:

SIGN OUT AMOUNT	DATE	TYPE	ADD/PARC SEC	ACTION	ENTERED BY	DATE	TIME
-----------------	------	------	--------------	--------	------------	------	------

*** End of Report ***

Primary / Tumor Site Discrepancy		✓

Source: NCI Genomic Data Commons file be2ba716-de96-47e8-a01f-81e7170a0a6f (TCGA-X9-A971.1BC7A87B-53D7-4DA1-A612-38B5495D9FCD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).